TCGA case TCGA-AJ-A2QK — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: International Genomics Conosrtium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/de5abe44-6d9d-4797-a57a-5adfd71383f0

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 65 years; Vital status: Alive.

Diagnoses (3)
1. Endometrioid adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 65.6 years (23,945 days); Year of diagnosis: 2011; Method of diagnosis: Dilation and Curettage Procedure; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 643 days (1.8 years).
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 6.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 25.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 18.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 48 days; Days to treatment end: 62 days; Treatment outcome: Complete Response; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Days to treatment start: 643 days (1.8 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 653 days (1.8 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
2. Metastasis of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Specified parts of peritoneum. Age at diagnosis: 67.2 years (24,551 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 606 days (1.7 years); Residual disease: R2.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Endometrioid adenocarcinoma, NOS), site: Liver. Age at diagnosis: 67.2 years (24,551 days); Days to diagnosis: 606 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 606 days (1.7 years); Residual disease: R2.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 12 days; Disease response: Tumor Free.
- Day 606 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 606 days (1.7 years).
- Day 606 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Specified parts of peritoneum; Days to progression: 606 days (1.7 years).
- Days to follow up: 643 days (1.8 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 119 kg; Height: 155 cm; BMI: 49.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AJ-A2QK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-AJ-A2QK-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 30; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-AJ-A2QK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AJ-A2QK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma.
- Follow-up form: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; History colorectal cancer: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response.
- Drug treatment 2: Pharmaceutical therapy drug name: Taxol.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 643 days; disease-specific survival: no event (censored), 643 days; disease-free interval: event (new tumor event after initially disease-free), 606 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 606 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AJ-A2QK-01A-11D-A18N-01): tumor purity 0.65, ploidy 1.78, whole-genome doublings 0.
